Gene-level copy-number profile of tumor specimen ALCH-B01S-TTP1-A from ALCHEMIST case ALCH-B01S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.3 years (28,233 days).
Specimen ALCH-B01S-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 533d4260-7919-4f4d-ad8d-26796aa211bf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B01S-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/0c08605c-a44d-4cc2-a453-9815e72ed37d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 693; copy number 2: 53,799; copy number 3: 3,718; copy number 4: 120; copy number 5: 3; copy number 6: 7; copy number 8: 12; copy number 10: 1; copy number 11: 2.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr7:56,805,336–56,808,148, 1 gene: CICP28.
- chr7:75,156,639–75,237,696, 6 genes: NCF1C, GTF2IP1, PHBP6, AC211486.5, AC211486.2, AC211486.4.
- chr9:134,054,290–134,058,805, 1 gene (within-gene range 0–2): AL445931.1.
- chr10:71,508,153–71,511,873, 1 gene (within-gene range 0–2): CDH23-AS1.
- chr10:117,542,445–117,549,546, 1 gene (within-gene range 0–2): EMX2.
- chr11:61,873,519–61,892,051, 2 genes: FADS3, MIR6746.
- chr12:122,834,453–122,862,961, 1 gene: HIP1R.
- chr14:104,681,146–104,722,535, 2 genes (within-gene range 0–2): INF2, AL583722.3.
- chr14:105,140,982–105,181,323, 4 genes: JAG2, MIR6765, AL512356.1, NUDT14.
- chr16:2,106,669–2,106,753, 1 gene (within-gene range 0–1): MIR6511B1.
- chr17:45,895,783–45,898,798, 1 gene (within-gene range 0–2): MAPT-IT1.
- chr19:1,259,384–1,274,880, 2 genes: CIRBP, CIRBP-AS1.
- chr19:3,094,362–3,123,999, 3 genes: GNA11, AC005262.2, KF456478.1.
- chr20:1,309,909–1,329,139, 1 gene (within-gene range 0–2): SDCBP2.
- chr20:62,352,995–62,356,480, 1 gene (within-gene range 0–2): LAMA5-AS1.
- chr21:45,981,769–46,005,050, 1 gene: COL6A1.
- chr22:18,951,934–18,959,512, 1 gene: AC007326.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 25 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:74,964,705–75,031,528, 1 gene, copy number 5 (within-gene range 3–5): CASTOR2.
- chr7:75,281,243–75,410,996, 13 genes, copy number 5–8 (within-gene range 2–44): SPDYE13, PMS2P10, Y_RNA, SPDYE14, AC211486.3, Y_RNA, SPDYE15, PMS2P2, Y_RNA, STAG3L1, Y_RNA, AC211486.1, TRIM73.
- chr15:30,103,720–30,179,943, 7 genes, copy number 6: ULK4P3, U8, GOLGA8T, RN7SL469P, DNM1P30, AC120045.2, AC120045.1.
- chr16:28,749,959–28,777,534, 3 genes, copy number 10–11: AC145285.5, NPIPB9, AC145285.7.
- chr16:90,173,217–90,222,851, 1 gene, copy number 5 (within-gene range 2–7): LINC02193.

Autosomal genes at a single copy (total copy number 1): 672. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
